MMRF case MMRF_2170 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e6b5c105-1d12-47e0-b851-83aa6e9ca55a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.6 years (20,305 days); ISS stage: III; Days to last known disease status: 862 days (2.4 years); Days to last follow up: 862 days (2.4 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 65 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 14 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 10 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 429 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 72 days; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 86 days; Days to treatment end: 429 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 862.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 3): M Protein 4.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 167 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.41 mg/dL; Immunoglobulin G 2.88 g/L; Immunoglobulin A 56.8 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 9.67 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 3.21 mmol/L; Albumin 39 g/L; Total Protein 10.9 g/dL; Glucose 5 mmol/L.
- Day 84 (ECOG 3): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Beta 2 Microglobulin 2.74 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 40 µmol/L; Blood Urea Nitrogen 7.6 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 4.8 mmol/L.
- Day 168 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 40 µmol/L; Blood Urea Nitrogen 3.9 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 6.9 mmol/L.
- Day 280: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Beta 2 Microglobulin 2.19 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 54 µmol/L; Blood Urea Nitrogen 4.9 mmol/L; Calcium 2.32 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.8 mmol/L.
- Day 346: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 3.7 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 3.7 mmol/L.
- Day 429: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Beta 2 Microglobulin 2.16 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 63 µmol/L; Blood Urea Nitrogen 3.8 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 5.3 mmol/L.
- Day 506: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 56 µmol/L; Blood Urea Nitrogen 5.3 mmol/L; Calcium 2.21 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 3.9 mmol/L.
- Day 632: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Beta 2 Microglobulin 2.16 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 58 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 4.6 mmol/L.
- Day 751: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Beta 2 Microglobulin 3.32 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 72 µmol/L; Blood Urea Nitrogen 5.7 mmol/L; Calcium 2.36 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day 0: Weight: 50 kg; Height: 154 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2170_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2170_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
